Somatic mutation profile of tumor specimen TCGA-EI-6509-01A (aliquot TCGA-EI-6509-01A-11D-1733-10) from TCGA case TCGA-EI-6509, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 53.8 years (19,666 days).
Specimen TCGA-EI-6509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f475d085-dee6-4d96-9a48-1529b069ce85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6509-10A (Blood Derived Normal), aliquot TCGA-EI-6509-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dcec199-bdb7-4b05-af9d-2868ab4baad1

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Frame Shift Ins 3, Nonsense Mutation 2, 3'UTR 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 135/166 reads (81%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 36/52 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1E2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as rs539686331, COSV53631102; called by muse, mutect2, varscan2
- ALMS1 | c.12491A>C p.K4164T | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52521436, COSV52524176; called by muse, mutect2, varscan2
- AQP6 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753948412, COSV100210264, COSV59646898; called by muse, mutect2, varscan2
- C7orf57 | c.603C>T p.P201= | Splice Region (SNP) | VAF 30/61 reads (49%) | catalogued as rs752606526, COSV100817342, COSV62364114; called by muse, mutect2, varscan2
- CMYA5 | c.6987G>T p.M2329I | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV71409331; called by muse, mutect2, varscan2
- CREB3 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59211593; called by muse, mutect2, varscan2
- DGKB | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV51817167; called by muse, mutect2, varscan2
- DNAL1 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV60728791; called by muse, mutect2, varscan2
- ELP6 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99948209, COSV99948211; called by muse, mutect2
- FBXO7 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56681358, COSV56681378; called by muse, mutect2, varscan2
- FSCB | c.421A>C p.T141P | Missense Mutation (SNP) | VAF 124/291 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV61219455; called by muse, mutect2, varscan2
- GALNTL5 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67181139; called by muse, mutect2, varscan2
- HLA-DQA1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs368821483; called by muse, mutect2, varscan2
- HRNR | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 103/213 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs371336025; called by muse, mutect2, varscan2
- INHBA | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV54220961, COSV54224244; called by muse, mutect2, varscan2
- IPO11 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764247262, COSV57582143; called by muse, mutect2, varscan2
- JMJD6 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV57975633; called by muse, mutect2, varscan2
- KCNN1 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55838709; called by muse, mutect2, varscan2
- LRBA | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63964340; called by muse, mutect2, varscan2
- LRP1B | c.3904C>A p.L1302I | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV67185227, COSV67272272; called by muse, mutect2, varscan2
- MACROH2A2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334883300, COSV100952362; called by muse, mutect2, varscan2
- MYOZ1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as rs756180269, COSV63771680; called by muse, mutect2, varscan2
- NES | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216557681, COSV63962584; called by muse, mutect2, varscan2
- NR0B1 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66764818; called by muse, mutect2, varscan2
- NRK | c.3308A>G p.Q1103R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs1362288549, COSV54606178; called by muse, mutect2, varscan2
- NSD3 | c.2913del p.Y971* | Frame Shift Del (DEL) | VAF 68/137 reads (50%) | catalogued as COSV57674016; called by mutect2, pindel, varscan2
- OAS2 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as rs541036111, COSV60804426; called by muse, mutect2, varscan2
- OTOP3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.782); catalogued as COSV60914941; called by muse, mutect2, varscan2
- PC | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs563526275, COSV58992595; called by muse, mutect2, varscan2
- PCDHB13 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV53400807; called by muse, mutect2, varscan2
- POU3F4 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV64540998, COSV64541025; called by muse, mutect2, varscan2
- PZP | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs757782402, COSV54369820; called by muse, mutect2, varscan2
- RASAL2 | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62722675; called by muse, mutect2, varscan2
- RBM34 | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64013411; called by muse, mutect2, varscan2
- RUNX1T1 | c.827A>T p.Y276F (on ENST00000265814 / NM_001198628.1; = p.Y249F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1219230544, COSV56162142; called by muse, mutect2, varscan2
- SFXN1 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs374767128; called by muse, mutect2, varscan2
- SNRPB | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 33/213 reads (15%) | catalogued as COSV60016522; called by muse, mutect2, varscan2
- SPANXB1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 128/1283 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.956); catalogued as rs1218463614; called by muse, mutect2, varscan2
- STC1 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1258190976, COSV51689983; called by muse, mutect2, varscan2
- UBE2K | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54693099; called by muse, mutect2, varscan2
- ZNF451 | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62599907; called by muse, mutect2, varscan2
- ADNP | c.64dup p.I22Nfs*3 | Frame Shift Ins (INS) | VAF 124/296 reads (42%) | called by mutect2, varscan2
- HGH1 | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPDZ | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2
- WIPI2 | c.682dup p.R228Kfs*13 | Frame Shift Ins (INS) | VAF 60/173 reads (35%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 38/109 reads (35%) | called by mutect2, pindel, varscan2
- ANXA8 | c.279G>A p.P93= | Silent (SNP) | VAF 332/2356 reads (14%) | catalogued as rs1383554593; called by muse, varscan2
- BICD1 | c.486G>A p.K162= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs750543466, COSV55685853; called by muse, mutect2, varscan2
- CACNA1H | c.4818G>A p.T1606= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs373457518, COSV100673343; called by muse, mutect2, varscan2
- CCDC170 | c.1998C>T p.T666= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as COSV53342582, COSV53345993; called by muse, mutect2, varscan2
- DNAH7 | c.874T>C p.L292= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as COSV56784679; called by muse, mutect2, varscan2
- MTRR | c.504G>C p.P168= (on ENST00000264668; = p.P141= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52943857, COSV52946724; called by muse, mutect2, varscan2
- PSG8 | c.475A>C p.R159= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV60615679; called by muse, mutect2, varscan2
- RYR3 | c.2121C>T p.D707= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as rs369220734; called by muse, mutect2, varscan2
- SEMA3F | c.1422C>T p.A474= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs540596745, COSV99137838; called by muse, mutect2, varscan2
- SLITRK4 | c.1806T>A p.T602= | Silent (SNP) | VAF 52/77 reads (68%) | catalogued as COSV62021972; called by muse, mutect2, varscan2
- TNNT3 | c.201C>T p.F67= (on ENST00000397301 / NM_001367846.1; = p.F56= on NM_006757.4) | Silent (SNP) | VAF 48/79 reads (61%) | catalogued as rs765194208, COSV53485054; called by muse, mutect2, varscan2
- ZACN | c.666G>A p.V222= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs201632789, COSV58037175; called by muse, mutect2, varscan2
- ZNF804A | c.3390G>A p.Q1130= | Silent (SNP) | VAF 73/148 reads (49%) | catalogued as COSV56470406; called by muse, mutect2, varscan2
- DST | c.4297-1836G>T | Intron (SNP) | VAF 17/50 reads (34%) | catalogued as COSV55038702; called by muse, mutect2, varscan2
- MYO1B | c.*1C>G | 3'UTR (SNP) | VAF 66/169 reads (39%) | catalogued as COSV100269817; called by muse, mutect2, varscan2
